TCGA case TCGA-QQ-A8VD — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e9f74a4-2f41-4b2f-b0e1-39c4d779bd40

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (4)
1. Abdominal fibromatosis (the primary disease): ICD-O-3 morphology code: 8822/1; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 56.8 years (20,729 days); Year of diagnosis: 2003; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 10; Tumor width measurement: 12.
   Pathology details: Measurement type: Radiologic; Tumor burden: 13.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 13.5; Tumor width measurement: 12.
   Pathology details: Measurement type: Pathologic; Tumor burden: 12.
2. Recurrence of diagnosis 1 (Abdominal fibromatosis), site: Abdomen, NOS. Age at diagnosis: 58.1 years (21,228 days); Days to diagnosis: 499 days (1.4 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 9.7; Tumor width measurement: 5.4.
   Pathology details: Measurement type: Pathologic; Tumor burden: 12.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6; Tumor length measurement: 12; Tumor width measurement: 8.
3. Recurrence of diagnosis 1 (Abdominal fibromatosis), site: Thorax, NOS. Age at diagnosis: 59.8 years (21,858 days); Days to diagnosis: 1,129 days (3.1 years); Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Abdominal fibromatosis), site: Abdomen, NOS. Age at diagnosis: 62.4 years (22,784 days); Days to diagnosis: 2,055 days (5.6 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 499 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 499 days (1.4 years).
- Day 1,129 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 1,129 days (3.1 years).
- Day 2,055 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 2,055 days (5.6 years).
- Days to follow up: 3,635 days (10.0 years); Disease response: With Tumor.
- Days to follow up: 3,964 days (10.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A8VD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-QQ-A8VD-01A-04-TSD: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-QQ-A8VD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A8VD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Desmoid Tumor; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Locoregional recurrence indicator: Yes; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Intraabdominal; Submitted tumor site: Retroperitoneum/Upper abdominal - Small Intestines.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic depth: 4; Lesion pathologic depth: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 529; Days from index date to pharmaceutical treatment ended: 1499; Pharmaceutical therapy drug name: Sulindac; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Ancillary.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 613; Days from index date to pharmaceutical treatment ended: 1499; Pharmaceutical therapy drug name: tamoxifen; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2, Therapy types: Pharmaceutical therapy type: Hormone Therapy.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2094; Days from index date to pharmaceutical treatment ended: 2780; Pharmaceutical therapy drug name: Gleevec; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Drug treatment 3, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2807; Days from index date to pharmaceutical treatment ended: 2886; Pharmaceutical therapy drug name: raloxifene; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2898; Days from index date to pharmaceutical treatment ended: 3026; Pharmaceutical therapy drug name: doxorubicin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 3939; Pharmaceutical therapy drug name: Sorafenib; Pharmaceutical treatment ongoing indicator: Yes.
- Radiation treatment 1: Days from index date to radiation therapy started: 1641; Days from index date to radiation therapy ended: 1684; Radiation therapy type: External; Radiation total dose: 54; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 30; Radiation therapy site: Local Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.
- Radiation treatment 2: Days from index date to radiation therapy started: 2348; Days from index date to radiation therapy ended: 2390; Radiation therapy type: External; Radiation total dose: 54; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 30; Radiation therapy site: Local Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,964 days; disease-specific survival: no event (censored), 3,964 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 499 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A8VD-01A-42D-A38Y-01): tumor purity 0.93, ploidy 2, whole-genome doublings 0.
